REBC case REBC-AF50 — Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine (REBC-THYR)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/2a090076-2a66-4e86-aaac-3b1d4d3514f6

Demographics
Sex at birth: male.

Diagnoses (1)
1. Papillary adenocarcinoma, NOS: ICD-O-3 morphology code: 8260/3; Tissue or organ of origin: Thyroid gland; Site of resection or biopsy: Thyroid gland.

Biospecimens (3 samples)
- Samples REBC-AF50-NT1, SC299525 (2 with the same recorded description): Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
- Sample REBC-AF50-TTP1: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
